Somatic mutation profile of tumor specimen HCM-BROD-0455-C71-01A (aliquot HCM-BROD-0455-C71-01A-11D-A78T-36) from HCMI case HCM-BROD-0455-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-BROD-0455-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cd70d37-cf89-428c-884e-59ded91c79f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0455-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0455-C71-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/385178e5-6835-4f0f-9037-c93edeba74c2

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 8, Intron 3, Frame Shift Del 3, RNA 2, In Frame Ins 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2316_2321dup p.H773_V774dup | In Frame Ins (INS) | VAF 69/361 reads (19%) | hotspot (GDC flag); catalogued as COSV51800933, COSV51820458; called by pindel, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 255/354 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CEP162 | c.2396_2399del p.D799Vfs*9 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | catalogued as rs751294869; called by mutect2, pindel, varscan2
- COL1A2 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 149/510 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs764373659, COSV99800278; called by muse, mutect2, varscan2
- DIS3L2 | c.1913G>A p.G638E | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs772936274; ClinVar: uncertain significance; called by muse, varscan2
- ELMO1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.027); catalogued as COSV60299879, COSV60302276; called by muse, mutect2, varscan2
- FLG | c.7769A>G p.N2590S | Missense Mutation (SNP) | VAF 172/673 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1034363980, COSV64241402; called by muse, mutect2, varscan2
- FLG | c.5529C>G p.H1843Q | Missense Mutation (SNP) | VAF 238/533 reads (45%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.917); catalogued as COSV100911597; called by muse, mutect2, varscan2
- FN1 | c.2856G>C p.Q952H | Missense Mutation (SNP) | VAF 193/629 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1196629506, COSV104396174; called by muse, mutect2, varscan2
- GPR173 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 96/116 reads (83%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.934); catalogued as rs782340108, COSV60234702; called by muse, mutect2, varscan2
- HMCN2 | c.11725G>A p.G3909R | Missense Mutation (SNP) | VAF 142/323 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs561629937; called by muse, mutect2, varscan2
- KRT8 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 198/576 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs764622352, COSV53176304, COSV99509888; called by muse, mutect2, varscan2
- PAN3 | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 43/111 reads (39%) | catalogued as COSV56703082; called by muse, mutect2, varscan2
- PCDHGA1 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 77/322 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs866208625, COSV65295357; called by muse, mutect2, varscan2
- PDILT | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs750176775, COSV56704382; called by muse, mutect2, varscan2
- PLCB1 | c.2208+1G>A p.X736_splice | Splice Site (SNP) | VAF 67/161 reads (42%) | catalogued as rs1235234848; called by muse, mutect2, varscan2
- PTPRQ | c.5836G>A p.V1946I (on ENST00000616559; = p.V1904I on NM_001145026.2) | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.341); catalogued as rs575071305, COSV57056778; called by muse, mutect2, varscan2
- PTPRZ1 | c.1390A>G p.T464A | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as rs759034684; called by muse, mutect2, varscan2
- RNASEL | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 132/415 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs758397188; called by muse, mutect2, varscan2
- SLCO1A2 | c.1084A>G p.N362D | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1031435942; called by muse, mutect2
- SST | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 91/204 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs764051709, COSV99809777; called by muse, mutect2, varscan2
- ZNF354A | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs148789422; called by muse, mutect2, varscan2
- AOC3 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 184/484 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ATRAID | c.803C>A p.S268Y (on ENST00000611786; = p.S155Y on NM_016085.5) | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- BFSP1 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 87/185 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C14orf39 | c.1161A>T p.E387D | Missense Mutation (SNP) | VAF 59/77 reads (77%) | SIFT tolerated (0.61); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FAM47A | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 98/141 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- GNPDA2 | c.300T>A p.D100E | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HOXA7 | c.520A>T p.I174F | Missense Mutation (SNP) | VAF 205/748 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IKZF1 | c.1480A>C p.M494L | Missense Mutation (SNP) | VAF 173/658 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- IL34 | c.543A>T p.K181N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, varscan2
- KLF15 | c.410T>C p.F137S | Missense Mutation (SNP) | VAF 116/303 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KLHL1 | c.37C>A p.H13N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); called by muse, varscan2
- KMT2E | c.638T>G p.I213S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- LAMC1 | c.1687G>C p.A563P | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- LRRC9 | c.133C>G p.P45A | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); called by muse, mutect2
- MCPH1 | c.55A>G p.N19D | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- OR8K1 | c.115A>T p.I39F | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2
- PLVAP | c.846G>C p.K282N | Missense Mutation (SNP) | VAF 70/258 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAG2 | c.3311del p.L1104* | Frame Shift Del (DEL) | VAF 64/99 reads (65%) | called by mutect2, pindel, varscan2
- TONSL | c.3928T>G p.F1310V | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ZBED9 | c.938del p.N313Ifs*30 | Frame Shift Del (DEL) | VAF 48/162 reads (30%) | called by mutect2, pindel, varscan2
- ACVRL1 | c.1390C>T p.L464= | Silent (SNP) | VAF 156/462 reads (34%) | catalogued as CD126266; called by muse, mutect2, varscan2
- KDM2A | c.1089G>A p.L363= | Silent (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- OR1S1 | c.810C>T p.G270= | Silent (SNP) | VAF 96/239 reads (40%) | catalogued as rs769712075, COSV58708680; called by muse, mutect2, varscan2
- PKM | c.165C>G p.S55= | Silent (SNP) | VAF 140/324 reads (43%) | called by muse, mutect2, varscan2
- PRF1 | c.1470C>T p.D490= | Silent (SNP) | VAF 182/255 reads (71%) | catalogued as rs759727585, COSV64615339; called by muse, mutect2, varscan2
- PROKR2 | c.990C>T p.T330= | Silent (SNP) | VAF 252/639 reads (39%) | catalogued as rs551444582, CD100862, COSV54087703; called by muse, mutect2, varscan2
- RAPGEF6 | c.3219C>T p.S1073= | Silent (SNP) | VAF 42/167 reads (25%) | called by muse, mutect2, varscan2
- RNF17 | c.4836G>A p.P1612= | Silent (SNP) | VAF 41/132 reads (31%) | catalogued as rs576396754, COSV99692481; called by muse, mutect2, varscan2
- AFF4 | c.964-42C>T | Intron (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- BOD1P2 | n.146C>T | RNA (SNP) | VAF 23/71 reads (32%) | catalogued as rs910280143; called by muse, mutect2, varscan2
- MRPL18 | c.52+19del | Intron (DEL) | VAF 67/179 reads (37%) | called by mutect2, pindel, varscan2
- PCYT1A | c.117+3111A>T | Intron (SNP) | VAF 57/180 reads (32%) | called by muse, mutect2, varscan2
- UBTFL2 | n.405A>G | RNA (SNP) | VAF 160/697 reads (23%) | called by muse, mutect2, varscan2
